Gene-level copy-number profile of tumor specimen ALCH-B3IF-TTP1-A from ALCHEMIST case ALCH-B3IF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 41.6 years (15,184 days).
Specimen ALCH-B3IF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ab16cbf4-5de8-4500-bb35-c95d76a5ba63.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3IF-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/c446c2be-358c-4437-ba86-8eac6b65194a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 48; copy number 1: 3,159; copy number 2: 51,877; copy number 3: 3,186; copy number 4: 55; copy number 5: 15; copy number 6: 13; copy number 7: 20; copy number 10: 5; copy number 11: 1; copy number 12: 6; copy number 14: 1; copy number 19: 1.

Homozygous deletions (total copy number 0; autosomes only): 48 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,011,997–1,013,193, 1 gene (within-gene range 0–2): AL645608.1.
- chr1:3,205,988–3,208,664, 1 gene (within-gene range 0–2): AL512383.1.
- chr1:3,454,665–3,481,113, 1 gene: ARHGEF16.
- chr1:11,785,723–11,806,455, 1 gene (within-gene range 0–2): MTHFR.
- chr5:176,707,356–176,743,871, 3 genes: AC113391.1, AC113391.2, LINC01574.
- chr8:41,840,059–41,840,339, 1 gene (within-gene range 0–2): RN7SL149P.
- chr9:35,749,287–35,758,585, 3 genes: RGP1, MSMP, AL133410.2.
- chr9:92,613,183–92,677,407, 2 genes (within-gene range 0–1): IPPK, AL137074.1.
- chr9:133,079,900–133,087,355, 1 gene (within-gene range 0–2): CELP.
- chr10:132,186,948–132,205,759, 1 gene: DPYSL4.
- chr11:2,268,495–2,270,952, 1 gene: ASCL2.
- chr15:25,174,927–25,209,999, 20 genes (within-gene range 0–1): SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22.
- chr15:25,239,838–25,250,940, 7 genes (within-gene range 0–1): SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:41,851,913–41,866,551, 2 genes (within-gene range 0–2): RNA5SP393, MIR4310.
- chr15:74,311,516–74,319,688, 1 gene (within-gene range 0–2): AC023300.2.
- chr19:53,299,051–53,308,644, 1 gene: FAM90A28P.
- chr21:44,107,373–44,131,181, 1 gene: PWP2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 62 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,295–133,723, 1 gene, copy number 6 (within-gene range 3–6): AL627309.1.
- chr1:131,025–522,928, 14 genes, copy number 5–6: CICP27, AL627309.6, AL627309.7, AL627309.2, RNU6-1100P, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr5:58,198–58,915, 1 gene, copy number 5: AC113430.1.
- chr5:61,610,424–61,793,401, 4 genes, copy number 6: C5orf64, AC026746.1, RNU6-913P, C5orf64-AS1.
- chr5:62,306,162–64,612,319, 19 genes, copy number 7: KIF2A, AC114982.2, DIMT1, IPO11, RNU6-661P, CKS1BP3, AC114982.1, RPL35AP14, LRRC70, ISCA1P1, AC113420.1, AC025445.1, HTR1A, AC122707.1, RNF180, AC091862.1, RGS7BP, RN7SL169P, RNU6-294P.
- chr9:60,914,407–60,964,196, 5 genes, copy number 10: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr9:136,196,250–136,205,128, 1 gene, copy number 5: LHX3.
- chr11:1,947,278–2,001,470, 7 genes, copy number 12–14: MRPL23, MRPL23-AS1, LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr19:18,434,388–18,438,167, 1 gene, copy number 5 (within-gene range 2–5): ISYNA1.
- chr19:40,447,765–40,465,764, 2 genes, copy number 5: BLVRB, Metazoa_SRP.
- chr21:43,115,334–43,162,277, 3 genes, copy number 5–7: MRPL51P2, FRGCA, AP001631.1.
- chr21:43,414,483–43,427,131, 1 gene, copy number 19: SIK1.
- chr21:43,461,960–43,479,534, 1 gene, copy number 11 (within-gene range 3–11): LINC00313.
- chr21:44,172,169–44,194,338, 2 genes, copy number 6: AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 3,159. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
